Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A431, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A431-01A (Primary Tumor).

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Skin *non-glabrous, per TSS.*

Tumor size: 3 x 3 x 1.5 cm

Tumor features: Ulcerated

Satellite nodules: Not specified

Histologic type: Nodular melanoma

Histologic grade:

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: 15 mm deep, III Level by Clarc

Dual/Synchronous Primary	Noted	
Reviewed (initials):	WHL	Date Reviewed: 8/1/12

ICD-O-3

melanoma, nodular
8721/3

Site: skin, NOS
C44.9

8-3-12
RD

Source: NCI Genomic Data Commons file 5a51e575-27ac-462e-a052-bbfb6b259911 (TCGA-EB-A431.BE192A00-38C3-4374-AC39-B27E66D83F10.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).